Somatic mutation profile of tumor specimen TARGET-20-PASJNM-09A (aliquot TARGET-20-PASJNM-09A-01D) from TARGET case TARGET-20-PASJNM, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 13.8 years (5,035 days).
Specimen TARGET-20-PASJNM-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cf519123-b139-42ac-96c7-178c1be982aa.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASJNM-14A (Bone Marrow Normal), aliquot TARGET-20-PASJNM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/cb249381-3c41-4485-9e86-f9b851a805e6

The open-access MAF lists 3 somatic variants for this specimen: 3 protein-altering or splice-affecting.
By variant classification: In Frame Del 1, Nonsense Mutation 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CEBPA | c.937_939dup p.K313dup | In Frame Ins (INS) | VAF 58/125 reads (46%) | catalogued as COSV57195821, COSV57196275, COSV57197455, COSV57199634, COSV57200242; called by mutect2, pindel, varscan2
- KMT2C | c.595C>T p.R199* | Nonsense Mutation (SNP) | VAF 56/116 reads (48%) | catalogued as COSV51443293; called by muse, mutect2, varscan2
- KMT2C | c.13810_13812del p.E4604del | In Frame Del (DEL) | VAF 50/132 reads (38%) | called by pindel, varscan2
